Surgical pathology report (de-identified scan), TCGA case TCGA-C4-A0F0, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Indivumed, specimen TCGA-C4-A0F0-01A (Primary Tumor).

ICD-0-3

Carcinoma, urothelial, NOS 8120/3

Site: bladder, NOS C67.9 1/28/11 *h*

Concluding diagnosis

Cystoprostatectomy preparation with a poorly differentiated urothelial carcinoma with foci of squamous epithelial differentiation. Max. tumor diameter 4 cm. Tumor infiltration as far as the boundary with the submucosa (no marked growth into the perivesical fatty tissue). Remaining bladder mucosa shows chronic inflammation. Urothelium without any clear-cut dysplasia at the preparation margins.
Tumor classification: pT2b, G3, L0, V0, tumor-free resection lines.

Source: NCI Genomic Data Commons file f7731296-fb03-4764-9f86-bd36f044b3f6 (TCGA-C4-A0F0.0A00B798-B309-4D11-8E16-3D7EE4AC1122.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).